Gene-level copy-number profile of tumor specimen TCGA-XF-A9T3-01A from TCGA case TCGA-XF-A9T3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.9 years (25,532 days).
Specimen TCGA-XF-A9T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0a8085cd-f452-4c64-9c03-346497840b43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9T3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/946234ed-735a-437a-b3cb-26ef704f8ff3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 399; copy number 2: 13,145; copy number 3: 26,068; copy number 4: 11,674; copy number 5: 7,076; copy number 6: 681; copy number 7: 318; copy number 8: 405; copy number 11: 1; copy number 12: 3; copy number 13: 10; copy number 23: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9T3-01A-11D-A42D-01): tumor purity 0.41, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 777 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr7:115,789,729–117,715,971, 50 genes, copy number 13–23 (within-gene range 6–23): AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1.
- chr7:133,253,073–134,066,589, 1 gene, copy number 12 (within-gene range 3–12): EXOC4.
- chr7:133,727,368–134,264,591, 3 genes, copy number 11–12 (within-gene range 3–12): COX5BP3, RPS3AP27, LRGUK.
- chr11:30,323,104–31,790,324, 13 genes, copy number 7 (within-gene range 5–7): ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1.

Autosomal genes at a single copy (total copy number 1): 399. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
